Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A1NW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A1NW-01A (Primary Tumor).

[page 1 of 6]
1CD 0.3

Adenocarcinoma, mixed serous and endometrioid 8441/3

Site: endometrium C541

2/24/11 per

Surgical Pathology

DIAGNOSIS:

- A. Soft tissue, ileal mesentery, biopsy: Involved by high grade serous adenocarcinoma.
- B. Soft tissue, small bowel serosa, biopsy: Involved by high grade serous adenocarcinoma.
- C. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: FIGO grade III (of III) adenocarcinoma with mixed serous and endometrioid features is identified forming multiple (2) irregular masses (4.2 x 1.6 x 1.4 cm and 0.7 x 0.4 x 0.2 cm) arising in a pedunculated endometrial polyp (7.5 x 3.8 x 2.9 cm), which fills the uterine cavity and is attached at the left posterior wall and cornu. The tumor is confined to the polyp and does not involve the myometrium. The tumor does not involve the endocervix. The tumor involves the posterior uterine serosa, cul de sac, adherent peritoneum and bilateral paraovarian soft tissue. Both ovaries and fallopian tubes are uninvolved. No definite lymphatic/vascular invasion is not identified. All surgical resection margins are negative for tumor. The background endometrium shows cystic atrophy.
- D. Vagina, anterior margin, excision: Negative for tumor.
- E. Lymph nodes, left pelvic, lymphadenectomy: Multiple (17) left pelvic lymph nodes are negative for metastatic carcinoma.

[page 2 of 6]
F. Lymph nodes, right pelvic, lymphadenectomy: Multiple (19) right pelvic lymph nodes are negative for metastatic carcinoma.

G. Appendix, appendectomy: Focal serosal involvement by high grade serous adenocarcinoma.

H. Omentum, omentectomy: High-grade serous adenocarcinoma forming multiple nodules (ranging in size from 0.2 to 8.0 cm in greatest dimension). Multiple (4) lymph node are identified.

I. Lymph nodes, right para-aortic above inferior mesenteric artery, lymphadenectomy: Multiple (5) right para-aortic lymph nodes above the inferior mesenteric artery, are negative for metastatic carcinoma.

J. Lymph nodes, right para-aortic below inferior mesenteric artery, lymphadenectomy: Multiple (6) right para-aortic lymph nodes below the inferior mesenteric artery, are negative for metastatic carcinoma.

K. Gonadal vessel, right, biopsy: Negative for tumor.

L. Lymph nodes, left para-aortic above inferior mesenteric artery, lymphadenectomy: Multiple (2 of 13) lymph nodes are focally positive for metastatic serous carcinoma.

M. Lymph nodes, left para-aortic below inferior mesenteric artery, lymphadenectomy: Multiple (2) lymph nodes are negative for metastatic carcinoma.

N. Gonadal vessel, left, biopsy: Negative for tumor.

[page 3 of 6]
O. Peritoneum, right pelvic sidewall, biopsy: Involved by high grade serous adenocarcinoma.

P. Peritoneum, left pelvic sidewall, biopsy: Involved by high grade serous adenocarcinoma.

With available surgical material [AJCC pT3bN2] (7th edition, 2010).

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "ileal mesentery nodule" is a 0.9 x 0.6 x 0.2 cm aggregate of pink-tan friable soft tissue with blood clot.

All submitted.

B. Received fresh labeled "small bowel serosa" is a 0.8 x 0.5 x 0.5 cm aggregate of pink-tan firm tissue. All submitted. Grossed by

C. Received fresh labeled "uterus, bilateral fallopian tubes and ovaries, bladder peritoneum" is a 164.1 gram uterus with attached bilateral tubes and ovaries. The uterine serosa has serosal

[page 4 of 6]
implants within the peritoneum. There is a 7.5 x 3.8 x 2.9 cm pedunculated polypoid mass filling the entire endometrial cavity, attached to the left posterior wall and cornu without invasion grossly. Within the polyp, there are two foci of firm, yellow cystic tissue (4.2 x 1.6 x 1.4 cm and 0.7 x 0.4 x 0.2 cm). The myometrial thickness is 1.4 cm. There are no leiomyomas. There is a 4.0 x 2.1 x 1.1 cm right ovary with a ragged outer surface and a solid cut surface with a 7.2 x 0.6 cm right fallopian tube which has serosal implants. There is a 3.7 x 2.0 x 0.9 cm left ovary with a ragged outer surface and a solid cut surface with a 6.2 x 0.7 cm left fallopian tube which has serosal implants. Attached is a 9.5 x 7.6 x 0.6 cm fragment of peritoneum which is grossly involved by tumor. Representative sections submitted.

D. Received fresh labeled "anterior vagina margin" is a 2.5 x 0.9 x 0.7 cm portion of tan-red mucosa without orientation. All submitted.

E. Received fresh labeled "left pelvic lymph nodes" is a 7.3 x 7.2 x 1.8 cm aggregate of adipose tissue and lymph nodes. All lymph nodes submitted.

F. Received fresh labeled "right pelvic lymph nodes" is a 7.9 x 7.0 x 1.8 cm aggregate of adipose tissue and lymph nodes. All lymph nodes submitted.

G. Received fresh labeled "appendix" is a 5.2 x 0.8 cm appendix with smooth serosa. There is no gross perforation. The lumen contains a fecalith. Representative sections submitted.

[page 5 of 6]
H. Received fresh labeled "omentum" is a 78.0 x 12.0 x 1.7 cm

portion of omentum. There are multiple nodules ranging from 0.2 cm

to 8.0 cm in greatest dimension. Lymph nodes are identified.

Representative sections are submitted.

I. Received fresh labeled "right para-aortic lymph nodes above IMA"

is a 3.2 x 2.8 x 1.0 cm aggregate of adipose and lymphatic tissue.

Lymph nodes submitted.

J. Received fresh labeled "right para-aortic lymph nodes below IMA"

is a 5.3 x 2.4 x 0.8 cm aggregate of adipose and lymphatic tissue.

Lymph nodes submitted.

K. Received fresh labeled "right gonadal vessel" is a 5.0 cm in

length by 0.5 cm in diameter portion of blood vessel and 5.0 x 2.0

cm attached adipose tissue. A representative section is submitted.

L. Received fresh labeled "left para-aortic lymph nodes above IMA"

is a 3.5 x 2.7 x 1.5 cm aggregate of adipose and lymphatic tissue.

Lymph nodes submitted.

M. Received fresh labeled "left para-aortic lymph nodes below IMA"

is a 4.2 x 1.5 x 1.3 cm aggregate of adipose and lymphatic tissue.

Lymph nodes submitted.

N. Received fresh labeled "left gonadal vessel" is a 4.3 cm in

length by 0.4 cm in diameter portion of unremarkable blood vessel.

A representative section is submitted.

O. Received fresh labeled "right pelvic sidewall peritoneum" is a

[page 6 of 6]
15.0 x 9.8 x 0.3 cm portion of red fibrous tissue, grossly involved

by innumerable tumor nodules. Representative sections are submitted.

P. Received fresh labeled "left pelvic sidewall peritoneum" is a

16.4 x 12.8 x 0.5 cm portion of red-tan fibrous tissue grossly

involved by innumerable tumor nodules. Representative sections are submitted.

Source: NCI Genomic Data Commons file c90cd612-af50-47d0-a6d1-798c939f86e7 (TCGA-D1-A1NW.10E1E872-408C-458D-9438-00F5ECA3083A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).